Gene-level copy-number profile of tumor specimen TCGA-BR-7716-01A from TCGA case TCGA-BR-7716, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 62.5 years (22,829 days).
Specimen TCGA-BR-7716-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.f7aa72c2-9965-4cbe-a306-03d583b08839.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-7716-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6bc1e757-ff3f-4f37-9455-542dd2b89c76

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,040; copy number 2: 19,822; copy number 3: 12,756; copy number 4: 15,156; copy number 5: 6,106; copy number 6: 1,307; copy number 7: 1,537; copy number 8: 13; copy number 9: 81; copy number 10: 43; copy number 11: 92; copy number 12: 782; copy number 13: 47; copy number 17: 6; copy number 19: 5; copy number 28: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-7716-01A-21D-2052-01): tumor purity 0.31, ploidy 2.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,039 genes in 50 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:94,418,389–94,895,246, 7 genes, copy number 5 (within-gene range 4–5): ABCD3, F3, AC093117.1, SLC44A3-AS1, KATNBL1P2, MIR378G, SLC44A3.
- chr1:209,661,364–211,654,627, 40 genes, copy number 5 (within-gene range 4–5): HSD11B1-AS1, G0S2, HSD11B1, ADORA2BP1, TRAF3IP3, C1orf74, IRF6, UTP25, SYT14, AL022397.1, SERTAD4-AS1, SERTAD4, ST13P19, AL035414.1, HHAT, AL034351.4, RNU5A-8P, AL034351.3, BPNT2P, KCNH1, AC096636.1, AL590132.1, IPO8P1, AC092017.2, AC092017.3, KCNH1-IT1, AC092017.1, PRELID1P5, RCOR3, TRAF5, AL590101.1, LINC00467, SNX25P1, ARPC3P2, RD3, AC105275.1, SLC30A1, AC105275.2, AL356310.1, LINC01693.
- chr1:234,669,523–248,919,946, 339 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr2:177,548,998–178,516,463, 21 genes, copy number 5: TTC30B, AC073834.1, TTC30A, PDE11A, PDE11A, PDE11A-AS1, AC011998.2, API5P2, SDHDP5, RNU6-629P, CYCTP, AC011998.1, RBM45, RNU5E-9P, OSBPL6, CHROMR, PRKRA, PJVK, NUDCP2, FKBP7, PLEKHA3.
- chr2:178,541,125–178,580,906, 5 genes, copy number 5: AC009948.2, AC009948.1, AC009948.3, AC010680.3, AC010680.2.
- chr3:171,058,414–174,378,005, 39 genes, copy number 5: TNIK, MIR569, Y_RNA, AC092919.1, AC092919.2, RNU6-348P, AC008134.1, PLD1, TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1, FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16, AC068759.1, NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1.
- chr3:175,938,929–176,867,838, 9 genes, copy number 5 (within-gene range 2–5): AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977, RNA5SP147, LINC01209.
- chr4:71,062,667–71,823,980, 6 genes, copy number 5 (within-gene range 4–5): SLC4A4, AC096713.1, LDHAL6EP, GC, RNA5SP163, AC068721.1.
- chr4:151,670,504–152,552,364, 25 genes, copy number 5: GATB, AC092611.1, AC107074.1, AC112242.2, AC112242.1, AC097375.2, AC097375.1, AC097375.4, AC097375.3, RNA5SP169, AC097375.5, LINC02273, AC079340.3, AC079340.1, AC079340.2, RN7SL446P, AC080078.1, AC080078.2, FBXW7, FBXW7-AS1, AC023424.2, MIR3140, MIR4453HG, MIR4453, RPS3AP18.
- chr4:171,812,254–190,092,279, 264 genes, copy number 6 (within-gene range 0–6) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 12 (broad region; genes not listed).
- chr5:172,755,457–172,952,683, 8 genes, copy number 5 (within-gene range 2–5): AC022217.2, AC022217.1, AC022217.3, DUSP1, Y_RNA, AC022217.4, AC110011.1, ERGIC1.
- chr5:179,963,615–181,342,213, 65 genes, copy number 5 (broad region; genes not listed).
- chr6:20,993,474–21,523,783, 6 genes, copy number 5: RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1.
- chr7:70,972–26,276,606, 421 genes, copy number 5–7 (broad region; genes not listed).
- chr7:39,329,003–40,134,622, 25 genes, copy number 6: SNORA20B, POU6F2-AS1, AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, AC004837.4, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1, CDK13, AC006023.2, AC006023.1, MPLKIP, Y_RNA.
- chr7:105,332,790–124,489,572, 243 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr7:147,080,934–159,233,377, 252 genes, copy number 5 (broad region; genes not listed).
- chr8:43,093,498–145,066,685, 1,559 genes, copy number 5–17 (broad region; genes not listed).
- chr10:44,712–27,100,494, 449 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr10:29,409,402–36,626,138, 125 genes, copy number 6–12 (broad region; genes not listed).
- chr10:47,300,197–49,815,562, 63 genes, copy number 6 (broad region; genes not listed).
- chr10:51,695,486–53,766,614, 14 genes, copy number 7: CSTF2T, PRKG1-AS1, DKK1, RPL31P44, THAP12P3, LNCAROD, MBL2, Y_RNA, AC073174.1, LINC02672, SNRPEP8, AC036101.1, RNA5SP318, AL365496.1.
- chr10:57,304,479–60,733,490, 32 genes, copy number 5 (within-gene range 2–5): MIR3924, AL731534.1, AC006484.1, MRPS35P3, AC026884.1, IPMK, TPT1P10, CISD1, AC016396.1, AC016396.2, UBE2D1, TFAM, BICC1, FAM133CP, RN7SKP196, LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1, AL355474.1, MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2.
- chr11:74,397,549–74,738,796, 15 genes, copy number 6: AP001372.1, AP001085.1, KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2, POLD3, RANP3, RN7SKP297, CHRDL2, AP001324.3, MIR4696, AP001324.2.
- chr11:121,238,304–123,675,569, 52 genes, copy number 5: AP001124.1, RPS4XP12, SC5D, BMPR1AP2, AP002365.1, AP000977.1, SORL1, AP001977.1, AP001924.1, RNU6-256P, AP001924.2, MIR100HG, MIR125B1, BLID, MIRLET7A2, MIR100, AP000755.1, AP000755.2, RNU4ATAC10P, RNU4ATAC5P, RNU6-592P, GLULP3, AP002469.1, UBASH3B, AP002762.3, AP002762.1, AP002762.2, CRTAM, JHY, RNU4-23P, ATP5PBP5, BSX, AP003040.1, RPL34P23, RPS26P43, RPL31P47, HSPA8, SNORD14E, SNORD14D, SNORD14C, AP000926.2, CLMP, AP000926.1, AP001970.1, U8, LINC02727, PHBP17, GRAMD1B, MIR4493, SF3A3P2, SCN3B, AP002765.1.
- chr12:50,979,401–133,214,832, 1,887 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr13:73,036,401–73,227,260, 6 genes, copy number 5: PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8.
- chr16:8,848,105–9,156,881, 12 genes, copy number 7 (within-gene range 1–7): AC022167.2, CARHSP1, AC022167.1, AC022167.4, LITAFD, USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119.
- chr16:27,066,707–35,086,119, 444 genes, copy number 5 (broad region; genes not listed).
- chr16:69,311,350–90,222,851, 575 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:19,296,596–19,633,825, 27 genes, copy number 7: EPN2-AS1, B9D1, MIR1180, AC124066.1, MAPK7, MFAP4, AC004448.5, RNF112, AC004448.3, AC004448.2, LINC02094, AC004448.4, RPS2P46, AC004448.1, SLC47A1, RPL17P43, SNORA59B, AC025627.1, SLC47A1P1, AC025627.2, AC025627.3, AC025627.4, MTND1P14, NMTRQ-TTG12-1, MTND2P12, MTCO1P39, SLC47A1P2.
- chr19:27,638,483–58,605,223, 1,686 genes, copy number 6–10 (broad region; genes not listed).
- chr20:5,407,564–5,929,318, 13 genes, copy number 5: AL121757.3, LINC00658, AL121757.1, LINC00654, LINC01729, RPS18P1, AL109935.1, GPCPD1, EIF4EP1, SHLD1, RNU1-55P, CHGB, KANK1P1.
- chr20:22,371,216–22,746,991, 7 genes, copy number 5 (within-gene range 3–5): AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3.
- chr20:31,257,664–32,673,941, 64 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr20:33,965,162–37,683,234, 129 genes, copy number 6 (broad region; genes not listed).
- chr20:39,655,325–41,024,394, 11 genes, copy number 5: AL132981.1, AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1, MAFB, AL035665.1, AL035665.2, RNA5SP484, RNU2-52P.
- chr20:43,558,968–54,070,594, 279 genes, copy number 6–28 (within-gene range 5–28) (broad region; genes not listed).
- chr22:48,320,412–50,801,309, 89 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,036. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
